Somatic mutation profile of tumor specimen 0DSI9I from CCDI case PBCIGV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.3 years (5,594 days).
Specimen 0DSI9I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2232bee-6415-4aaf-b4a6-20908e560f12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSI8C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd886123-7009-43c2-8bd0-518a6c825c53

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASAP1 | c.1997-2A>G p.X666_splice | Splice Site (SNP) | VAF 270/815 reads (33%) | catalogued as COSV63047669; called by muse, mutect2, varscan2
- ZNF845 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1239350099, COSV72004794; called by mutect2, varscan2
- CFAP251 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 47/1253 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- GOLGA4 | c.1244A>T p.E415V | Missense Mutation (SNP) | VAF 46/1100 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHF3 | c.5012A>T p.D1671V | Missense Mutation (SNP) | VAF 342/992 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TMEM87A | c.673C>G p.P225A | Missense Mutation (SNP) | VAF 133/490 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK5 | c.2343G>A p.K781= | Silent (SNP) | VAF 29/692 reads (4%) | called by muse, mutect2
- HPCA | c.114C>T p.C38= | Silent (SNP) | VAF 30/642 reads (5%) | catalogued as rs1196653286; called by muse, mutect2
- COX6B2 | c.-19+44G>T | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- FAM50A | c.-28_-19dup | 5'UTR (INS) | VAF 6/45 reads (13%) | called by mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/40 reads (10%) | catalogued as COSV55814242; called by muse, mutect2
